CCDI case PBBYNI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f61025e8-d4fd-42d1-9654-d011f0e9da10

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.3 years (7,052 days).

Biospecimens (3 samples)
- Sample 0DLA0X: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLA1W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DLA2R: Tissue type: Tumor; Specimen type: Solid Tissue.
